Somatic mutation profile of tumor specimen TCGA-06-0241-01A (aliquot TCGA-06-0241-01A-02D-1491-08) from TCGA case TCGA-06-0241, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.0 years (24,101 days).
Specimen TCGA-06-0241-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 325fc94a-5dbc-40bc-8326-a3211b06f3eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0241-10A (Blood Derived Normal), aliquot TCGA-06-0241-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85395525-14b6-44aa-998d-9f2cbc0797bf

The open-access MAF lists 62 somatic variants for this specimen: 43 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 36, Silent 19, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 40/64 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD50 | c.1340T>C p.L447S | Missense Mutation (SNP) | VAF 115/283 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV72386062; called by muse, mutect2, varscan2
- AQP10 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.509); catalogued as rs773423264, COSV61475889; called by muse, mutect2, varscan2
- ARL8B | c.290A>G p.D97G | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56579322; called by muse, mutect2, varscan2
- CSF3R | c.2069C>T p.T690M | Missense Mutation (SNP) | VAF 111/236 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs764345289, COSV58969888; called by muse, mutect2, varscan2
- ELSPBP1 | c.17G>C p.S6T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs1383509194, COSV60414544; called by muse, mutect2, varscan2
- FAM83H | c.3502G>A p.V1168M | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369901205, COSV62027504; called by muse, mutect2, varscan2
- FANCI | c.3928A>G p.T1310A (on ENST00000310775 / NM_001376911.1; = p.T1250A on NM_018193.3) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV51523811; called by muse, mutect2, varscan2
- FBN1 | c.2471G>A p.S824N | Missense Mutation (SNP) | VAF 204/473 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV57325865; called by muse, mutect2, varscan2
- KIAA1109 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs553523360, COSV52678203; called by muse, mutect2, varscan2
- KIF4A | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs201310458, COSV65544870; called by muse, mutect2, varscan2
- KLF8 | c.371C>A p.T124K | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV63848462; called by muse, mutect2, varscan2
- LRP1B | c.5122T>A p.Y1708N | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV67255872; called by muse, mutect2, varscan2
- MAGEB4 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 55/126 reads (44%) | catalogued as rs1332884014, COSV66776302; called by muse, mutect2, varscan2
- MAGI1 | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770193154, COSV58322664; called by muse, mutect2, varscan2
- MBIP | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 59/72 reads (82%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV59254881; called by muse, mutect2, varscan2
- MEGF6 | c.4566G>A p.A1522= | Splice Region (SNP) | VAF 36/61 reads (59%) | catalogued as rs542498064, COSV53888615; called by muse, mutect2, varscan2
- MUC5B | c.1274G>A p.C425Y | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71594376; called by muse, mutect2, varscan2
- NAV2 | c.5290G>A p.A1764T (on ENST00000396087 / NM_001244963.2; = p.A1708T on NM_145117.5) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.986); catalogued as rs769042839, COSV60661293; called by muse, mutect2, varscan2
- NEU1 | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 102/204 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV57668591; called by muse, mutect2, varscan2
- NOL3 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.825); catalogued as COSV50458755; called by muse, mutect2, varscan2
- NOX4 | c.1405T>G p.F469V | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV54462562; called by muse, mutect2
- OR13C8 | c.919G>T p.V307F | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV58612218, COSV58612543; called by muse, mutect2
- PEG3 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs200022665, COSV55630963; called by muse, mutect2, varscan2
- POU5F1 | c.592T>C p.C198R | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52564553; called by muse, mutect2, varscan2
- RBM27 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54592714; called by muse, mutect2, varscan2
- RGN | c.786C>G p.C262W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100282445, COSV60276690; called by muse, varscan2
- RIC1 | c.2917G>A p.D973N | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1450328839, COSV52613395; called by muse, mutect2, varscan2
- RTEL1 | c.3145G>T p.V1049L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV53928666; called by muse, mutect2, varscan2
- SH3D19 | c.320C>G p.P107R | Missense Mutation (SNP) | VAF 106/243 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58792576; called by muse, mutect2, varscan2
- SLC9A6 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 117/294 reads (40%) | catalogued as COSV65788706; called by muse, mutect2, varscan2
- TAB3 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761956021, COSV55835086, COSV55839426; called by muse, mutect2, varscan2
- TENT5C | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.984); catalogued as rs538766512, COSV65616490; called by muse, mutect2, varscan2
- TESK1 | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV52412010; called by muse, mutect2, varscan2
- TMEM79 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); catalogued as COSV55296717; called by muse, mutect2, varscan2
- TNNT1 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.553); catalogued as rs765133367, COSV52572899; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP11 | c.359G>A p.G120E (on ENST00000218348; = p.G77E on NM_001371072.1) | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV54475226; called by muse, mutect2, varscan2
- YEATS2 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 107/264 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.627); catalogued as rs200810151; called by muse, varscan2
- ZNF697 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV70284282, COSV70284302; called by muse, mutect2, varscan2
- CNOT4 | c.2103del p.T702Qfs*80 (on ENST00000541284 / NM_001190850.1; = p.T628Qfs*? on NM_013316.4) | Frame Shift Del (DEL) | VAF 147/744 reads (20%) | called by mutect2, pindel, varscan2
- IGKV2-30 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- L3MBTL1 | c.1802del p.G601Dfs*78 (on ENST00000418998 / NM_001377303.1; = p.G511Dfs*78 on NM_015478.7) | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel
- PCDH17 | c.623dup p.H208Qfs*28 | Frame Shift Ins (INS) | VAF 28/87 reads (32%) | called by mutect2, pindel, varscan2
- AKAP13 | c.2673C>T p.D891= | Silent (SNP) | VAF 78/178 reads (44%) | catalogued as COSV63465660; called by muse, mutect2, varscan2
- ATRX | c.3510A>G p.Q1170= | Silent (SNP) | VAF 130/270 reads (48%) | catalogued as COSV64880927; called by muse, mutect2, varscan2
- COL4A6 | c.3648C>T p.I1216= | Silent (SNP) | VAF 68/145 reads (47%) | catalogued as rs1252478935, COSV57873608; called by muse, mutect2, varscan2
- DNAJC2 | c.1659T>C p.P553= | Silent (SNP) | VAF 135/488 reads (28%) | catalogued as rs759297684, COSV50787214; called by muse, mutect2, varscan2
- GPR174 | c.876C>T p.Y292= | Silent (SNP) | VAF 79/204 reads (39%) | catalogued as COSV52133652; called by muse, mutect2, varscan2
- HIVEP2 | c.6894T>C p.T2298= | Silent (SNP) | VAF 60/162 reads (37%) | catalogued as COSV50035612; called by muse, mutect2, varscan2
- ITGA9 | c.777G>A p.P259= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs145062473; called by muse, mutect2, varscan2
- ITGAM | c.1407C>T p.N469= | Silent (SNP) | VAF 159/368 reads (43%) | catalogued as rs377233362; called by muse, mutect2, varscan2
- KCTD19 | c.513G>A p.E171= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as COSV58574268; called by muse, mutect2, varscan2
- LRP1 | c.6975C>T p.V2325= | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as rs372464430; called by muse, mutect2, varscan2
- MAGI2 | c.1350G>A p.L450= | Silent (SNP) | VAF 54/177 reads (31%) | catalogued as COSV62685437; called by muse, mutect2, varscan2
- NDST1 | c.1959A>G p.K653= | Silent (SNP) | VAF 162/395 reads (41%) | catalogued as COSV55789592; called by muse, mutect2, varscan2
- PCDHA2 | c.1671C>T p.D557= | Silent (SNP) | VAF 62/164 reads (38%) | catalogued as COSV65366364; called by muse, varscan2
- RELN | c.2016G>A p.P672= | Silent (SNP) | VAF 36/131 reads (27%) | catalogued as rs146749232, COSV59016458; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SPATA31A1 | c.3966G>A p.Q1322= | Silent (SNP) | VAF 145/188 reads (77%) | catalogued as COSV66533755; called by muse, mutect2, varscan2
- TBC1D8 | c.1098C>A p.I366= | Silent (SNP) | VAF 136/291 reads (47%) | catalogued as COSV65209460, COSV65214975; called by muse, mutect2, varscan2
- TBXT | c.1119C>A p.A373= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV51618273; called by muse, mutect2, varscan2
- THEG | c.822G>A p.P274= | Silent (SNP) | VAF 97/229 reads (42%) | catalogued as rs768597942, COSV61074526; called by muse, mutect2, varscan2
- UBQLN2 | c.1740C>T p.V580= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV57740257; called by muse, mutect2, varscan2
